TCGA case TCGA-AL-A5DJ — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Fox Chase. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b06cdf61-61c9-4035-a55d-1ef21dc21069

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Dead; Days to death: 1,498 days (4.1 years).

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 55.0 years (20,079 days); Year of diagnosis: 2009; AJCC staging edition: 3rd; AJCC clinical T: T1b; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage I; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,498 days (4.1 years).
   Pathology details: Consistent pathology review: Yes; Prcc type: Type 2.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Temsirolimus; Days to treatment start: 355 days; Days to treatment end: 475 days (1.3 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Thyroid gland; Classification of tumor: Prior primary; Age at diagnosis: 40.2 years (14,668 days); Days to diagnosis: -5,411 days (-14.8 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -5,411 days (-14.8 years); Treatment anatomic sites: Thyroid.

Follow-up (3 entries)
- Days to follow up: 26 days; Disease response: Tumor Free.
- Days to follow up: 1,498 days (4.1 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Molecular and laboratory tests
- Hemoglobin: Low.
- Platelets: Normal.
- Leukocytes: Low.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 165 cm; BMI: 23.5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AL-A5DJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 280 mg.
  Slide TCGA-AL-A5DJ-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AL-A5DJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AL-A5DJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Performance status timing: Post Secondary Therapy; Hemoglobin level: Low; White cell count: Low; Lymph nodes examined: No; Tobacco smoking history indicator: 1; New tumor event diagnosis indicator: No.
- Drug treatment: Treatment best response: Clinical Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: Thyroid Papillary Carcinoma - Classical/usual.
- Other malignancy form, Surgery: Other malignancy surgery type: radical thyroidectomy.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: unknown treatment history.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,498 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,498 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,498 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AL-A5DJ-01): tumor purity 0.66, ploidy 2.89, whole-genome doublings 1 (call status: maf_call).
